Somatic mutation profile of tumor specimen TCGA-55-7910-01A (aliquot TCGA-55-7910-01A-11D-2167-08) from TCGA case TCGA-55-7910, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 50.1 years (18,289 days).
Specimen TCGA-55-7910-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33ffac91-52e1-468f-a5e2-d1e17d206147.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-7910-11A (Solid Tissue Normal), aliquot TCGA-55-7910-11A-01D-2167-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3778951-657a-4b5b-8820-f115c0969dc3

The open-access MAF lists 331 somatic variants for this specimen: 259 protein-altering or splice-affecting, 64 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 226, Silent 64, Nonsense Mutation 20, Frame Shift Del 6, Splice Site 6, RNA 4, 5'UTR 1, Frame Shift Ins 1, 3'UTR 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 15/27 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.358A>G p.K120E | Missense Mutation (SNP) | VAF 31/52 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912658, CM921039, COSV52676498, COSV52692352, COSV53551619, COSV53685479; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.1741+1G>T p.X581_splice | Splice Site (SNP) | VAF 34/73 reads (47%) | catalogued as rs1445940737, COSV57052342; called by muse, mutect2, varscan2
- ABCB1 | c.749C>A p.A250D | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV55949146; called by muse, mutect2
- ABCB11 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs760754635, COSV55597033; called by muse, mutect2, varscan2
- AC100868.1 | c.1731G>T p.R577S | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.274); catalogued as COSV51841195; called by muse, mutect2, varscan2
- ACSM2A | c.383G>A p.R128Q (on ENST00000219054; = p.R49Q on NM_001308169.2) | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs770257438, COSV54583992; called by muse, mutect2, varscan2
- ACSM2A | c.812G>A p.C271Y (on ENST00000219054; = p.C192Y on NM_001308169.2) | Missense Mutation (SNP) | VAF 97/230 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV54584010; called by muse, mutect2, varscan2
- ADAM18 | c.1768G>T p.D590Y | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.793); catalogued as COSV55846199, COSV99695915; called by muse, mutect2, varscan2
- ADAMTS12 | c.4644C>A p.F1548L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV61260721; called by muse, mutect2, varscan2
- ADAMTS16 | c.2977G>T p.G993W | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56979014, COSV56985648; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3891G>T p.E1297D | Missense Mutation (SNP) | VAF 131/297 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.056); catalogued as COSV54444351; called by muse, mutect2, varscan2
- AL592490.1 | c.2762G>T p.R921M | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.319); catalogued as COSV69425735, COSV69427467; called by muse, mutect2, varscan2
- ALDH1A3 | c.747G>T p.Q249H | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV60901462; called by muse, mutect2, varscan2
- AMELX | c.411C>A p.H137Q | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV61626490; called by muse, mutect2, varscan2
- ANGPT2 | c.1282G>A p.G428R | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.143); catalogued as COSV57336354; called by muse, mutect2, varscan2
- ANK2 | c.4712G>A p.C1571Y | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as COSV52156535; called by muse, mutect2, varscan2
- ANO6 | c.726G>T p.K242N | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.099); catalogued as COSV57659908; called by muse, mutect2, varscan2
- ARFGEF3 | c.1941C>G p.C647W | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.168); catalogued as COSV52455405; called by muse, mutect2, varscan2
- ARHGAP10 | c.1657C>T p.L553F | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV60597918; called by muse, mutect2, varscan2
- ARHGAP29 | c.1307A>G p.Q436R | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV53110669; called by muse, mutect2, varscan2
- ARSF | c.707G>T p.S236I | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.093); catalogued as COSV63839359; called by muse, mutect2, varscan2
- ASTN2 | c.718C>A p.P240T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV57770268; called by muse, varscan2
- ATP13A3 | c.2238G>T p.M746I | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55463564, COSV55463805; called by muse, mutect2, varscan2
- BCOR | c.3095A>T p.E1032V | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60705382; called by muse, mutect2, varscan2
- BDP1 | c.1229G>T p.C410F | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV62430764; called by muse, mutect2, varscan2
- BIRC6 | c.13596G>T p.M4532I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101428429; called by muse, mutect2
- BLID | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV73340212; called by muse, mutect2, varscan2
- BMP3 | c.133G>T p.G45C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV51082972; called by muse, varscan2
- BRINP3 | c.1057C>G p.R353G | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.088); catalogued as COSV66520603; called by muse, mutect2, varscan2
- BTG4 | c.662G>T p.R221I | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as COSV63635123, COSV63635581; called by muse, mutect2, varscan2
- BTN1A1 | c.1426G>T p.A476S | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT tolerated (0.54); PolyPhen benign (0.033); catalogued as COSV55067310; called by muse, mutect2, varscan2
- C1QB | c.674C>A p.T225N | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV59245254; called by muse, mutect2, varscan2
- C7orf33 | c.443C>G p.T148R | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.118); catalogued as rs909640056, COSV61022978; called by muse, mutect2, varscan2
- C8A | c.557G>T p.R186M | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63483723; called by muse, mutect2, varscan2
- C8orf34 | c.642G>C p.W214C | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV61376981; called by muse, mutect2, varscan2
- CACNA1I | c.3818T>A p.V1273D | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60805906; called by muse, mutect2, varscan2
- CCDC115 | c.480G>T p.W160C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.929); catalogued as COSV52091610, COSV52092828; called by muse, mutect2, varscan2
- CCDC33 | c.1523A>C p.H508P | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as COSV51499666, COSV51500279; called by muse, mutect2, varscan2
- CD163 | c.2075C>A p.S692* | Nonsense Mutation (SNP) | VAF 106/124 reads (85%) | catalogued as COSV63131535, COSV63134805; called by muse, mutect2, varscan2
- CES3 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.542); catalogued as COSV57593239; called by muse, mutect2, varscan2
- CFAP43 | c.3791G>A p.R1264Q | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs754109266, COSV63852814; called by muse, mutect2, varscan2
- CFAP65 | c.266G>T p.G89V (on ENST00000341552 / NM_194302.4; = p.G24V on NM_152389.4) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.178); catalogued as rs1024222161, COSV55390008; called by muse, mutect2, varscan2
- CHRM5 | c.550C>A p.Q184K | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.953); catalogued as COSV67247176; called by muse, mutect2, varscan2
- CMKLR1 | c.499G>A p.A167T (on ENST00000312143 / NM_001142344.2; = p.A165T on NM_004072.3) | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV56437622; called by muse, mutect2, varscan2
- CNKSR2 | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 154/315 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV54253952; called by muse, mutect2, varscan2
- COL11A1 | c.4966G>T p.E1656* | Nonsense Mutation (SNP) | VAF 15/80 reads (19%) | catalogued as COSV62180327; called by muse, mutect2, varscan2
- COL28A1 | c.2323-1G>T p.X775_splice | Splice Site (SNP) | VAF 13/29 reads (45%) | catalogued as COSV68080803; called by muse, mutect2, varscan2
- COL5A1 | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs777065347, COSV65667939; called by muse, mutect2
- CSMD3 | c.4966G>T p.G1656* (on ENST00000297405 / NM_001363185.1; = p.G1552* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV52148190; called by muse, mutect2, varscan2
- CSMD3 | c.1184G>T p.R395L | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.018); catalogued as COSV52105622, COSV52155991; called by muse, mutect2, varscan2
- CSN2 | c.346C>G p.P116A | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.355); catalogued as COSV61992032; called by mutect2, varscan2
- DACH2 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs748093037, COSV64165833, COSV64182277; called by muse, mutect2
- DAW1 | c.1091G>T p.S364I | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59364815; called by muse, mutect2, varscan2
- DCAF12L2 | c.330G>T p.Q110H | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63581217; called by muse, mutect2, varscan2
- DCAF8L1 | c.623G>C p.G208A | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71595231; called by muse, mutect2, varscan2
- DCBLD1 | c.168G>T p.K56N | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51640052; called by muse, mutect2, varscan2
- DCLK3 | c.872G>T p.R291L | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as COSV69362945; called by muse, mutect2, varscan2
- DDX53 | c.149C>A p.P50Q | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1043024354, COSV60068850; called by muse, mutect2, varscan2
- DEF6 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as rs764306600, COSV57353079; called by muse, mutect2, varscan2
- DHX30 | c.389G>C p.R130P (on ENST00000445061 / NM_138615.3; = p.R91P on NM_014966.3) | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.457); catalogued as COSV62394236, COSV62395630; called by muse, mutect2, varscan2
- DNAAF6 | c.115C>A p.L39I | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.538); catalogued as COSV60495626; called by muse, mutect2, varscan2
- DOCK10 | c.2036C>T p.P679L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51377225; called by muse, mutect2, varscan2
- DSCAML1 | c.6273C>A p.S2091R (on ENST00000321322; = p.S2031R on NM_020693.4) | Missense Mutation (SNP) | VAF 54/90 reads (60%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.097); catalogued as COSV58388381; called by muse, mutect2, varscan2
- DZIP3 | c.1184A>G p.H395R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.987); catalogued as rs762057179, COSV64311695, COSV64311740; called by mutect2, varscan2
- ECE1 | c.935C>T p.T312M | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.767); catalogued as rs867547949, COSV51663549; called by muse, mutect2, varscan2
- EIF4G3 | c.3386G>A p.R1129H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs745779320, COSV51679916; called by muse, mutect2
- EPHX4 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV100952724; called by muse, varscan2
- EWSR1 | c.533G>A p.S178N | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1181333034, COSV58423024; called by muse, mutect2
- EXD3 | c.1966G>T p.G656C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV59803479, COSV59803867; called by muse, mutect2, varscan2
- F7 | c.1187G>T p.S396I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.439); catalogued as COSV60645812; called by muse, mutect2, varscan2
- F8 | c.6563G>A p.C2188Y | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1278160877, CM054683, COSV57704881; called by muse, mutect2, varscan2
- FAM47B | c.1356C>A p.D452E | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.879); catalogued as COSV61453358; called by muse, mutect2, varscan2
- FBN2 | c.6230G>T p.G2077V | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52507575; called by muse, mutect2, varscan2
- FIGN | c.2205G>T p.K735N | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV100291321, COSV100292564; called by muse, mutect2, varscan2
- FLRT2 | c.1760A>T p.D587V | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV58139871; called by muse, mutect2, varscan2
- FN3KRP | c.520C>G p.Q174E | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as COSV53929423; called by muse, mutect2, varscan2
- FOXN4 | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV54493464; called by muse, mutect2, varscan2
- FOXP3 | c.323C>G p.T108R | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.238); catalogued as CM066087, COSV66050927, COSV66051140; called by muse, mutect2, varscan2
- FZD10 | c.1252G>T p.V418L | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV57473200; called by muse, mutect2, varscan2
- GAB2 | c.1862C>A p.P621Q (on ENST00000361507 / NM_080491.3; = p.P583Q on NM_012296.3) | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142455789, COSV60867164; called by muse, mutect2, varscan2
- GABRA3 | c.43G>C p.G15R | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated, low confidence (0.35); PolyPhen probably damaging (0.996); catalogued as COSV64797640, COSV64806802; called by muse, mutect2, varscan2
- GALNT3 | c.583A>G p.N195D | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV67061645; called by muse, mutect2, varscan2
- GALNT6 | c.1726C>T p.P576S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV62541993; called by muse, mutect2, varscan2
- GFRAL | c.803C>T p.T268I | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV61229568; called by muse, mutect2, varscan2
- GNL3L | c.991C>A p.P331T | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV60576020; called by muse, mutect2, varscan2
- GPC5 | c.1517G>T p.G506V | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1038806269, COSV65585963, COSV65591876; called by muse, mutect2, varscan2
- GPER1 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV52468646; called by muse, mutect2, varscan2
- GPR83 | c.718G>T p.D240Y | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54718295; called by muse, mutect2, varscan2
- GPX7 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV63652547, COSV63652830; called by muse, mutect2, varscan2
- GRIN1 | c.1776C>A p.N592K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.194); catalogued as COSV59294621; called by muse, mutect2, varscan2
- GRM5 | c.3568T>A p.C1190S (on ENST00000305447 / NM_001143831.2; = p.C1158S on NM_000842.4) | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.952); catalogued as COSV59601005; called by muse, mutect2, varscan2
- GRM6 | c.1104A>C p.K368N | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as COSV51439117; called by muse, mutect2, varscan2
- HDAC2 | c.126G>T p.L42F | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64037888; called by muse, mutect2, varscan2
- HERC2 | c.10348G>A p.E3450K | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.025); catalogued as COSV55319050; called by muse, mutect2
- HERC5 | c.1879G>A p.V627I | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.266); catalogued as rs148569726; called by muse, mutect2, varscan2
- HIVEP2 | c.2144G>T p.S715I | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV50009012; called by muse, mutect2, varscan2
- HOMEZ | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV62536791; called by muse, mutect2, varscan2
- HOXA1 | c.962C>A p.P321H | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58029464; called by muse, mutect2, varscan2
- HPSE2 | c.13T>A p.C5S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV65187019; called by muse, mutect2, varscan2
- IFT74 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); catalogued as rs746236439, COSV66286573; called by muse, mutect2, varscan2
- IGFALS | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | catalogued as rs768231769, CM081663, COSV51905474; called by muse, mutect2, varscan2
- IL9R | c.224A>T p.Q75L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.083); catalogued as COSV54899109; called by muse, mutect2, varscan2
- IMPDH1 | c.1105G>T p.V369L (on ENST00000470772 / NM_001142573.2; = p.V455L on NM_000883.4) | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV58315694; called by muse, mutect2, varscan2
- INTS7 | c.1071G>C p.R357S | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.037); catalogued as COSV100877527; called by muse, mutect2, varscan2
- ISL2 | c.727C>G p.R243G | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51957648; called by muse, mutect2
- ITGAD | c.2956G>T p.A986S | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as rs777340351, COSV54931762; called by muse, mutect2, varscan2
- ITGB5 | c.850G>T p.A284S | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs776835945, COSV56146846, COSV56148331; called by muse, mutect2, varscan2
- ITGB8 | c.2109C>G p.I703M | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); catalogued as COSV56007221; called by muse, mutect2, varscan2
- JADE2 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as COSV50914175; called by muse, mutect2, varscan2
- KCNK2 | c.43G>T p.G15* | Nonsense Mutation (SNP) | VAF 13/111 reads (12%) | catalogued as COSV67204984; called by muse, mutect2, varscan2
- KDM6B | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs377714300; called by muse, mutect2, varscan2
- KIAA1109 | c.7517C>T p.P2506L | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV52669352; called by muse, mutect2, varscan2
- KIAA1549L | c.1445T>A p.L482H (on ENST00000321505; = p.L779H on NM_012194.3) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.541); catalogued as COSV55772268; called by muse, mutect2, varscan2
- KIF7 | c.3450C>A p.D1150E | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51540573; called by muse, mutect2, varscan2
- KLHL34 | c.1850G>T p.R617L | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs146464429, COSV65279143; called by muse, mutect2, varscan2
- KLHL4 | c.1300G>C p.V434L | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV100909872, COSV64142569, COSV64149443; called by muse, mutect2, varscan2
- KRT16 | c.769G>T p.E257* | Nonsense Mutation (SNP) | VAF 45/75 reads (60%) | catalogued as COSV56967655; called by muse, mutect2, varscan2
- LPAR2 | c.194A>C p.Q65P | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.699); catalogued as COSV52555537, COSV52555891; called by muse, mutect2, varscan2
- LRP1B | c.12217C>A p.P4073T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67207429; called by muse, mutect2, varscan2
- LRP1B | c.4802C>A p.T1601K | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67207435; called by muse, mutect2, varscan2
- LRP1B | c.3491del p.P1164Lfs*15 | Frame Shift Del (DEL) | VAF 38/144 reads (26%) | catalogued as COSV67247944; called by mutect2, pindel*, varscan2
- LRRC4 | c.652G>T p.V218L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as COSV50813692; called by muse, mutect2, varscan2
- MAPK14 | c.329G>C p.G110A | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); catalogued as COSV57695423; called by muse, mutect2, varscan2
- MBD1 | c.1147-2A>G p.X383_splice (on ENST00000269468 / NM_001323950.1; = p.X327_splice on NM_002384.2) | Splice Site (SNP) | VAF 32/59 reads (54%) | catalogued as COSV54000216; called by muse, mutect2, varscan2
- MCM6 | c.2035G>T p.G679C | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as COSV51465832; called by muse, mutect2, varscan2
- MCM7 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as rs748597030, COSV57995726, COSV58000591; called by muse, mutect2, varscan2
- MELK | c.1147A>T p.T383S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as COSV53198258; called by muse, mutect2, varscan2
- MID2 | c.538C>G p.R180G | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1292953974, COSV53308721; called by muse, mutect2, varscan2
- MMP2 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs777819097, COSV54600313; called by muse, mutect2, varscan2
- MOSPD2 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 22/130 reads (17%) | catalogued as COSV66859902; called by muse, mutect2, varscan2
- MTA1 | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs781986255, COSV58756758; called by muse, mutect2, varscan2
- MTBP | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.063); catalogued as COSV59962294; called by muse, mutect2, varscan2
- MYF5 | c.670C>A p.L224I | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as COSV57354917, COSV57356365; called by muse, mutect2, varscan2
- MYOM2 | c.2813C>A p.A938E | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.959); catalogued as COSV50708585; called by muse, mutect2, varscan2
- NCAPH | c.1803G>T p.Q601H | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.364); catalogued as COSV53635997; called by muse, mutect2, varscan2
- NLRP10 | c.835A>T p.R279W | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60779934; called by muse, mutect2, varscan2
- NOTCH4 | c.3050C>T p.P1017L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV66680164; called by muse, mutect2, varscan2
- NRXN1 | c.1883C>A p.P628H | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1344637711, COSV58446779, COSV58492144; called by muse, mutect2, varscan2
- NSDHL | c.110C>A p.A37D | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV64743658, COSV64744157; called by muse, mutect2, varscan2
- NT5C1B | c.1488T>A p.C496* (on ENST00000359846 / NM_001199086.2; = p.C436* on NM_033253.4) | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as COSV58395472; called by muse, mutect2, varscan2
- NUF2 | c.1231G>T p.A411S | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.78); PolyPhen benign (0.015); catalogued as COSV54843338; called by muse, mutect2, varscan2
- OGDHL | c.1216G>A p.V406M | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs781448685, COSV65101265; called by muse, mutect2, varscan2
- OPN3 | c.946-2A>T p.X316_splice | Splice Site (SNP) | VAF 21/92 reads (23%) | catalogued as COSV100087550; called by muse, mutect2, varscan2
- OR1C1 | c.363T>A p.D121E | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV68715651; called by muse, mutect2, varscan2
- OR2D2 | c.591G>A p.M197I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV55056837; called by muse, mutect2, varscan2
- OR2T27 | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100788162, COSV61281551; called by muse, mutect2
- OR4C16 | c.150C>G p.S50R | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV58941569, COSV58943979; called by muse, mutect2, varscan2
- OR4K17 | c.363C>A p.D121E | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59647880; called by muse, mutect2, varscan2
- OR5D16 | c.728G>A p.C243Y | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV65721671; called by muse, mutect2, varscan2
- OR5T1 | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as rs549381739, COSV57302453; called by muse, mutect2, varscan2
- OR5T3 | c.737G>T p.R246M | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV57380166; called by muse, mutect2, varscan2
- OTUD6A | c.809A>T p.N270I | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57973087; called by muse, mutect2
- PACRGL | c.224G>C p.R75P | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV54841678, COSV99764249; called by muse, mutect2, varscan2
- PARP12 | c.1694G>T p.G565V | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54933475; called by muse, mutect2, varscan2
- PARP12 | c.1182+1G>T p.X394_splice | Splice Site (SNP) | VAF 35/187 reads (19%) | catalogued as COSV54933488; called by muse, mutect2, varscan2
- PARP14 | c.1315T>G p.S439A | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.444); catalogued as COSV71734444; called by muse, mutect2, varscan2
- PCDH11X | c.3203G>T p.G1068V | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV53458303; called by muse, mutect2, varscan2
- PCDHB14 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 46/81 reads (57%) | catalogued as COSV53387904; called by muse, mutect2, varscan2
- PCLO | c.6248C>G p.T2083S | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV100434142, COSV61628466; called by muse, mutect2
- PEG3 | c.3653C>A p.P1218H | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55630865; called by muse, mutect2, varscan2
- PHLDB2 | c.2751G>T p.M917I (on ENST00000393925 / NM_001134439.2; = p.M874I on NM_145753.2) | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs367684981; called by muse, mutect2, varscan2
- PIGN | c.2703G>T p.M901I | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.164); catalogued as COSV62948894; called by muse, mutect2, varscan2
- PKP2 | c.2423A>G p.Q808R | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV50729074; called by muse, mutect2, varscan2
- PLEKHA6 | c.13A>G p.T5A | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55332383; called by muse, mutect2
- PPFIA4 | c.2620A>T p.I874F (on ENST00000447715; = p.I875F on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV55313994; called by muse, mutect2, varscan2
- PPP2R2B | c.680C>A p.A227E (on ENST00000394409; = p.A293E on NM_181674.2) | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV60762400; called by muse, mutect2, varscan2
- PRG4 | c.2507C>G p.P836R | Missense Mutation (SNP) | VAF 66/269 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as COSV63355274; called by muse, mutect2, varscan2
- PRLR | c.592C>A p.P198T | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as COSV99184499; called by muse, mutect2, varscan2
- PRODH2 | c.1227G>T p.Q409H (on ENST00000301175; = p.Q333H on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.382); catalogued as COSV56559311; called by muse, mutect2, varscan2
- PROKR2 | c.212A>G p.N71S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775950405, COSV54086060; called by muse, mutect2, varscan2
- PRUNE2 | c.7524G>T p.K2508N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV65040557; called by muse, mutect2
- PTHLH | c.431G>T p.R144L | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52367431; called by muse, mutect2, varscan2
- PTPRT | c.2922G>T p.M974I | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100626541, COSV61975141; called by muse, mutect2, varscan2
- QSOX2 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.656); catalogued as COSV62393868; called by muse, mutect2, varscan2
- RAD51AP2 | c.720G>T p.Q240H | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV67587800; called by muse, mutect2, varscan2
- REG3G | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV55449069, COSV55450717; called by muse, mutect2, varscan2
- RELN | c.6926A>T p.D2309V | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58996833; called by muse, mutect2
- REM1 | c.460G>T p.G154C | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52427794; called by muse, mutect2, varscan2
- RERGL | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs369374785; called by muse, mutect2, varscan2
- RIN2 | c.1885T>G p.S629A (on ENST00000255006 / NM_001242581.1; = p.S580A on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.453); catalogued as COSV54786859; called by muse, mutect2
- RSBN1 | c.262C>A p.Q88K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); catalogued as COSV54732073; called by muse, mutect2, varscan2
- RTCB | c.1285G>A p.G429R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs967594700, COSV53278377; called by muse, mutect2, varscan2
- RTL3 | c.1359T>A p.H453Q | Missense Mutation (SNP) | VAF 45/60 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58183875; called by muse, mutect2, varscan2
- SACS | c.4724G>C p.R1575P | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.146); catalogued as CM107270, COSV66538374, COSV66538520; called by muse, mutect2, varscan2
- SAMD9L | c.4691G>T p.R1564I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV100560865, COSV59082109; called by muse, mutect2, varscan2
- SCN10A | c.1329C>A p.H443Q | Missense Mutation (SNP) | VAF 58/86 reads (67%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV71860996; called by muse, mutect2, varscan2
- SEMA3A | c.2158G>T p.E720* | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | catalogued as COSV54867578; called by muse, mutect2, varscan2
- SEMA3D | c.157C>G p.L53V | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.082); catalogued as COSV52391588; called by muse, mutect2, varscan2
- SIRPG | c.927C>A p.N309K | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53806934; called by muse, mutect2, varscan2
- SLC27A6 | c.1004C>A p.A335E | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52482207; called by muse, mutect2, varscan2
- SLC38A8 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1387496280, COSV55305948, COSV55305998; called by muse, mutect2, varscan2
- SLC5A6 | c.44C>G p.S15W | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV60159148; called by muse, mutect2, varscan2
- SLFN5 | c.533G>T p.R178I | Missense Mutation (SNP) | VAF 55/87 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as COSV55480700; called by muse, mutect2, varscan2
- SLITRK3 | c.2845del p.Q949Kfs*8 | Frame Shift Del (DEL) | VAF 27/250 reads (11%) | catalogued as COSV53849364; called by mutect2, pindel, varscan2
- SLITRK3 | c.1348G>A p.G450R | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.44); PolyPhen probably damaging (1); catalogued as COSV53847344; called by muse, mutect2, varscan2
- SNRK | c.1556C>T p.P519L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV56067494; called by muse, mutect2, varscan2
- SNX24 | c.191G>A p.R64K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.946); catalogued as COSV54450634; called by muse, mutect2, varscan2
- SPATA31A1 | c.1406C>A p.A469D | Missense Mutation (SNP) | VAF 118/744 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.647); catalogued as rs1391131696; called by muse, mutect2, varscan2
- SPATA31A3 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.073); catalogued as rs1452892698; called by mutect2, varscan2
- SPINT4 | c.259C>A p.R87S | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV54142341, COSV54142606; called by muse, mutect2, varscan2
- SPTLC3 | c.600T>A p.H200Q | Missense Mutation (SNP) | VAF 8/165 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65464911; called by muse, mutect2
- SRPK3 | c.277G>C p.V93L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV54207091; called by muse, mutect2, varscan2
- ST18 | c.398T>A p.L133* | Nonsense Mutation (SNP) | VAF 23/47 reads (49%) | catalogued as COSV52491096; called by muse, mutect2, varscan2
- STK11IP | c.1473G>T p.R491S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV55247814; called by muse, mutect2, varscan2
- SYNJ2 | c.3258G>T p.E1086D | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV62896826; called by muse, mutect2, varscan2
- TAF1 | c.1105G>T p.E369* (on ENST00000373790 / NM_138923.4; = p.E390* on NM_004606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 51/159 reads (32%) | catalogued as COSV52111374; called by muse, mutect2, varscan2
- TAF1 | c.2587G>T p.E863* (on ENST00000373790 / NM_138923.4; = p.E884* on NM_004606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 60/120 reads (50%) | catalogued as COSV52111396; called by muse, mutect2, varscan2
- TBC1D8B | c.2521C>T p.Q841* | Nonsense Mutation (SNP) | VAF 53/266 reads (20%) | catalogued as COSV52177970; called by muse, mutect2, varscan2
- TECRL | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.628); catalogued as COSV101169095; called by muse, varscan2
- TENM1 | c.4018A>T p.I1340F | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV64430080; called by muse, mutect2, varscan2
- TGM6 | c.1514C>A p.P505H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99171837; called by muse, mutect2, varscan2
- TIMELESS | c.2612G>T p.G871V | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57510662; called by muse, mutect2, varscan2
- TLL1 | c.1265G>T p.R422I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50273215, COSV50287064; called by muse, mutect2, varscan2
- TMEM214 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 3/47 reads (6%) | catalogued as COSV99476401; called by muse, mutect2
- TMEM63C | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53602569; called by muse, mutect2, varscan2
- TNC | c.6511C>A p.H2171N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60783660; called by muse, mutect2, varscan2
- TNN | c.307G>T p.G103C | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as COSV53424850; called by muse, mutect2, varscan2
- TRHR | c.1037C>A p.A346D | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.197); catalogued as COSV61233575; called by muse, mutect2, varscan2
- TRIM2 | c.362A>G p.H121R (on ENST00000437508; = p.H148R on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58632702; called by muse, mutect2, varscan2
- TRIM44 | c.711G>T p.L237F | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV54983488; called by muse, mutect2, varscan2
- TRIM8 | c.166A>T p.N56Y | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV56660293; called by muse, mutect2, varscan2
- TRPC3 | c.2099G>T p.G700V (on ENST00000379645 / NM_001366479.2; = p.G627V on NM_003305.2) | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53374361; called by muse, mutect2, varscan2
- TTLL11 | c.938A>T p.D313V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV58645322; called by muse, mutect2, varscan2
- TTN | c.38838T>A p.Y12946* (on ENST00000591111; = p.Y5522* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | catalogued as COSV59994797; called by muse, varscan2
- UBALD1 | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52081969; called by muse, mutect2
- UGT2B28 | c.1166C>G p.P389R | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59431463; called by muse, mutect2
- VCAN | c.652T>A p.Y218N | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV54103170; called by muse, mutect2, varscan2
- VGLL1 | c.362G>T p.R121M | Missense Mutation (SNP) | VAF 57/286 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.359); catalogued as COSV65703195; called by muse, mutect2, varscan2
- VGLL3 | c.285G>T p.Q95H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV67352848; called by muse, mutect2, varscan2
- VPS13B | c.8650C>T p.Q2884* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as COSV62139002; called by muse, mutect2, varscan2
- VPS50 | c.1950A>G p.I650M | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV58506948; called by muse, mutect2, varscan2
- VWC2L | c.161T>A p.V54D | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56968945; called by muse, mutect2, varscan2
- WNT11 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.357); catalogued as rs1046121955, COSV59443551; called by muse, mutect2, varscan2
- XIRP2 | c.7720C>G p.L2574V (on ENST00000628543; = p.L2749V on NM_152381.6) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV54694251; called by muse, mutect2, varscan2
- XK | c.221T>G p.L74R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66120043; called by muse, mutect2, varscan2
- XPNPEP2 | c.352T>A p.W118R | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64367854; called by muse, mutect2, varscan2
- XPOT | c.445A>G p.I149V | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as rs759203434, COSV60344863; called by muse, mutect2, varscan2
- ZCCHC14 | c.272A>T p.K91I (on ENST00000268616; = p.K228I on NM_015144.3) | Missense Mutation (SNP) | VAF 60/348 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV51885466; called by muse, mutect2, varscan2
- ZFHX4 | c.3872C>A p.P1291Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50683968; called by muse, mutect2, varscan2
- ZFHX4 | c.8002G>T p.V2668L | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV51466963, COSV51506078; called by muse, mutect2, varscan2
- ZIC3 | c.897G>T p.W299C | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54973612; called by muse, mutect2, varscan2
- ZMYND15 | c.1378G>C p.G460R (on ENST00000433935 / NM_001136046.3; = p.V460L on NM_032265.2) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.999); catalogued as COSV52641248; called by muse, mutect2, varscan2
- ZNF131 | c.1310G>T p.R437M (on ENST00000509156 / NM_001330707.2; = p.R403M on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/140 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV61002233; called by muse, mutect2, varscan2
- ZNF195 | c.521G>T p.G174V (on ENST00000399602 / NM_001130520.3; = p.G102V on NM_007152.5) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV50003077; called by muse, mutect2, varscan2
- ZNF33A | c.1811G>T p.G604V (on ENST00000458705 / NM_006974.3; = p.G605V on NM_006954.2) | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100275616, COSV56724376; called by muse, mutect2, varscan2
- ZNF423 | c.3322G>C p.A1108P (on ENST00000563137 / NM_001379286.1; = p.A1100P on NM_015069.4) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.043); catalogued as COSV52185154; called by muse, varscan2
- ZNF530 | c.1292G>T p.G431V | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60531326; called by muse, mutect2, varscan2
- ZNF680 | c.1196T>A p.I399N | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV59015010; called by muse, mutect2, varscan2
- ZNF711 | c.815G>A p.S272N | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52153148; called by muse, mutect2, varscan2
- ZNF770 | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV62544189; called by muse, mutect2, varscan2
- ZNF772 | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.881); catalogued as COSV58410660; called by mutect2, varscan2
- ANKS1A | c.2306G>T p.G769V | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- APCDD1 | c.419del p.G140Afs*13 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | called by mutect2, pindel, varscan2
- GRID2 | c.2565del p.W855* | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel, varscan2
- IMPG1 | c.547dup p.I183Nfs*20 | Frame Shift Ins (INS) | VAF 13/71 reads (18%) | called by mutect2, pindel, varscan2
- KIF19 | c.2408_2409del p.P803Rfs*40 | Frame Shift Del (DEL) | VAF 18/32 reads (56%) | called by mutect2, pindel, varscan2
- TCTEX1D1 | c.357_358del p.D120Lfs*7 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | called by mutect2, pindel, varscan2
- TMC2 | c.555-2_555-1del p.X185_splice | Splice Site (DEL) | VAF 11/29 reads (38%) | called by mutect2, pindel*, varscan2*
- ACSL6 | c.1473C>T p.L491= (on ENST00000379240; = p.L516= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/78 reads (50%) | catalogued as rs144740812, COSV57297186, COSV57299406; called by muse, mutect2, varscan2
- ACTBL2 | c.129C>T p.G43= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs766613102, COSV70661069; called by muse, mutect2, varscan2
- ACTL8 | c.837C>T p.S279= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs551868811, COSV64861087; called by muse, mutect2, varscan2
- ADAM2 | c.603C>T p.V201= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs199916948, COSV55861072, COSV55865270; called by muse, mutect2, varscan2
- AMY2B | c.756G>T p.L252= | Silent (SNP) | VAF 22/165 reads (13%) | catalogued as rs1364880436, COSV63714962; called by muse, mutect2, varscan2
- ANK1 | c.4839C>A p.P1613= | Silent (SNP) | VAF 23/166 reads (14%) | catalogued as COSV55879145, COSV99225935; called by muse, mutect2, varscan2
- ANKRD44 | c.2247C>T p.A749= | Silent (SNP) | VAF 58/192 reads (30%) | catalogued as COSV56553423; called by muse, mutect2, varscan2
- ANKS1B | c.2583G>T p.G861= (on ENST00000547776 / NM_152788.4; = p.G87= on NM_020140.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100228276; called by muse, mutect2, varscan2
- AREL1 | c.1962G>C p.A654= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV100707576, COSV62665828, COSV62666151; called by muse, mutect2, varscan2
- ARPP21 | c.1137C>T p.T379= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs1372776449, COSV51795664; called by muse, mutect2, varscan2
- ASAH2 | c.1026A>G p.V342= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV61483109; called by muse, mutect2, varscan2
- ASPM | c.9189A>T p.I3063= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV54127829; called by muse, mutect2, varscan2
- CD177 | c.141C>A p.T47= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV65121188; called by muse, mutect2, varscan2
- COL4A1 | c.3279A>T p.P1093= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as COSV65424216; called by muse, mutect2, varscan2
- COL6A3 | c.846G>T p.G282= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV99799386; called by muse, mutect2, varscan2
- CPNE6 | c.1614C>A p.G538= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as rs1168531892, COSV53743680; called by muse, mutect2, varscan2
- CRACD | c.2104C>A p.R702= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as rs528871147, COSV51719395; called by muse, mutect2, varscan2
- CSMD3 | c.1560C>A p.G520= (on ENST00000297405 / NM_001363185.1; = p.G416= on NM_052900.3) | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV52155977, COSV52234883; called by muse, mutect2, varscan2
- DCDC1 | c.5259T>C p.Y1753= (on ENST00000597505 / NM_001367979.1; = p.Y860= on NM_020869.3) | Silent (SNP) | VAF 24/34 reads (71%) | catalogued as COSV57998627; called by muse, mutect2, varscan2
- DDX24 | c.1300C>T p.L434= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV58212244; called by muse, mutect2, varscan2
- DHX57 | c.603G>A p.A201= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs747041632, COSV54884307; called by muse, mutect2, varscan2
- EGLN3 | c.48G>T p.L16= | Silent (SNP) | VAF 27/205 reads (13%) | catalogued as COSV51654517; called by muse, mutect2, varscan2
- GUCY1A2 | c.1887G>A p.V629= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV56484179; called by muse, mutect2, varscan2
- HAPLN2 | c.351C>G p.G117= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV54815566, COSV99660952; called by muse, mutect2, varscan2
- HECTD4 | c.12489G>T p.A4163= | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as COSV66390305; called by muse, mutect2, varscan2
- HPD | c.156C>A p.T52= | Silent (SNP) | VAF 57/135 reads (42%) | catalogued as COSV56641699; called by muse, mutect2, varscan2
- HS3ST1 | c.447G>T p.P149= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV50023377, COSV50023690; called by muse, mutect2, varscan2
- IGHV1-24 | c.306G>T p.L102= | Silent (SNP) | VAF 61/201 reads (30%) | called by muse, mutect2, varscan2
- IGHV1-58 | c.306G>T p.L102= | Silent (SNP) | VAF 33/178 reads (19%) | called by muse, mutect2, varscan2
- KCNC1 | c.633C>A p.T211= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV56393419; called by muse, mutect2, varscan2
- KCTD14 | c.618G>T p.A206= | Silent (SNP) | VAF 59/94 reads (63%) | catalogued as COSV62001066, COSV62001309; called by muse, mutect2, varscan2
- KCTD16 | c.438C>T p.S146= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs147117374; called by muse, mutect2, varscan2
- LIMK1 | c.865C>A p.R289= | Silent (SNP) | VAF 10/234 reads (4%) | catalogued as rs191821726, COSV60280954, COSV60283387; called by muse, mutect2
- MED13 | c.4530G>T p.A1510= | Silent (SNP) | VAF 111/172 reads (65%) | catalogued as COSV67263054; called by muse, mutect2, varscan2
- MICB | c.906G>A p.V302= | Silent (SNP) | VAF 24/35 reads (69%) | catalogued as COSV52856169; called by muse, mutect2, varscan2
- MRAP2 | c.51T>A p.S17= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV57631780, COSV57632135; called by muse, mutect2, varscan2
- MYCBP2 | c.10980C>G p.V3660= (on ENST00000357337; = p.V3698= on NM_015057.5) | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV62015685; called by muse, mutect2, varscan2
- MYO15A | c.6768G>A p.G2256= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs1404878831, COSV52755258; called by muse, mutect2
- MYT1L | c.2454C>A p.P818= | Silent (SNP) | VAF 35/101 reads (35%) | catalogued as COSV67717489; called by muse, mutect2, varscan2
- NHS | c.2208C>A p.A736= | Silent (SNP) | VAF 55/107 reads (51%) | catalogued as COSV66273835; called by muse, mutect2, varscan2
- NSMF | c.762C>T p.S254= (on ENST00000371475 / NM_001130969.3; = p.S252= on NM_015537.4) | Silent (SNP) | VAF 31/130 reads (24%) | catalogued as rs754993835, COSV52997564; called by muse, mutect2, varscan2
- OR10A2 | c.900C>T p.N300= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs1293381464, COSV56299105; called by muse, mutect2, varscan2
- OR51F2 | c.711G>C p.R237= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV59064473; called by muse, mutect2, varscan2
- OR5D14 | c.351G>C p.L117= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV59456034; called by muse, mutect2, varscan2
- P2RY14 | c.561A>T p.S187= | Silent (SNP) | VAF 41/113 reads (36%) | catalogued as rs200238332, COSV56375787; called by muse, mutect2, varscan2
- PCLO | c.13956A>T p.S4652= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV61619492; called by muse, varscan2
- PDSS1 | c.1032A>T p.P344= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV61016406; called by muse, mutect2, varscan2
- PRDX4 | c.210C>A p.A70= | Silent (SNP) | VAF 44/74 reads (59%) | catalogued as COSV65018634, COSV65018736; called by muse, mutect2, varscan2
- PRKCH | c.2010G>A p.E670= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV60647513; called by muse, mutect2, varscan2
- RAP1B | c.108A>T p.I36= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV51668088; called by muse, mutect2, varscan2
- RB1CC1 | c.4426T>C p.L1476= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV50246319; called by muse, mutect2, varscan2
- RCHY1 | c.483C>T p.V161= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV61008307; called by muse, mutect2, varscan2
- RELN | c.6924C>A p.I2308= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as COSV58996842, COSV59031603; called by muse, mutect2
- RHCG | c.759C>T p.T253= | Silent (SNP) | VAF 36/55 reads (65%) | catalogued as COSV51515451; called by muse, mutect2, varscan2
- RIMS2 | c.3144C>A p.T1048= (on ENST00000666250 / NM_001348490.2; = p.T856= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as COSV99174368; called by muse, mutect2, varscan2
- SAMD14 | c.601C>A p.R201= | Silent (SNP) | VAF 19/21 reads (90%) | catalogued as COSV50303482; called by muse, mutect2, varscan2
- SCG2 | c.453T>C p.Y151= | Silent (SNP) | VAF 48/123 reads (39%) | catalogued as COSV59539613; called by muse, mutect2, varscan2
- SHANK1 | c.5412A>T p.S1804= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as COSV53247766; called by muse, mutect2
- SHANK2 | c.5085C>T p.P1695= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV53594561; called by muse, mutect2, varscan2
- SLITRK3 | c.1095C>A p.T365= | Silent (SNP) | VAF 136/252 reads (54%) | catalogued as COSV53847357, COSV53850850; called by muse, mutect2, varscan2
- TBX22 | c.648C>A p.S216= | Silent (SNP) | VAF 91/178 reads (51%) | catalogued as COSV64785657; called by muse, mutect2, varscan2
- TPBG | c.702C>T p.P234= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as rs775912512, COSV63882500; called by muse, mutect2, varscan2
- WAS | c.1176C>A p.P392= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV100939508; called by muse, mutect2, varscan2
- WSCD2 | c.138G>T p.S46= | Silent (SNP) | VAF 74/185 reads (40%) | catalogued as COSV54581381, COSV54588548; called by muse, mutect2, varscan2
- CLLU1 | chr12:92422580 C>G | 5'Flank (SNP) | VAF 6/15 reads (40%) | catalogued as COSV65902963; called by muse, mutect2, varscan2
- DCHS2 | n.4230C>T | RNA (SNP) | VAF 6/24 reads (25%) | catalogued as rs1270004959, COSV61770446, COSV61775926; called by muse, mutect2, varscan2
- DKC1 | c.771+220C>A | Intron (SNP) | VAF 11/57 reads (19%) | catalogued as COSV101059887; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.762C>T | RNA (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- NBPF25P | n.600C>A | RNA (SNP) | VAF 10/240 reads (4%) | called by muse, mutect2
- SSPOP | n.1272C>G | RNA (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100022693; called by muse, mutect2, varscan2
- TESMIN | c.*2G>T | 3'UTR (SNP) | VAF 68/106 reads (64%) | catalogued as COSV99663796; called by muse, mutect2, varscan2
- UBE2U | c.-1C>T | 5'UTR (SNP) | VAF 5/47 reads (11%) | catalogued as rs1320564630, COSV100934446; called by muse, mutect2, varscan2
